Somatic mutation profile of tumor specimen MP2PRT-PARBBV-TMP1-A (aliquot MP2PRT-PARBBV-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARBBV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,220 days).
Specimen MP2PRT-PARBBV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89b364e5-e6e8-4662-b898-9f9b95eea977.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARBBV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARBBV-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25b0831b-016a-4632-8aa7-ce17bfaf87c9

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 95/275 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTDP1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 162/862 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs1260669909, COSV50003417, COSV99311077; called by muse, varscan2
- KRTAP4-6 | c.240C>A p.C80* | Nonsense Mutation (SNP) | VAF 173/506 reads (34%) | catalogued as COSV61981539, COSV61981630; called by muse, mutect2, varscan2
- OR4K13 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 70/354 reads (20%) | catalogued as rs998479002, COSV100237682; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406864 TACCCCATTCAC>GGACTGG | Missense Mutation (DEL) | VAF 39/180 reads (22%) | called by pindel, varscan2*
- PLCL1 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRKCE | c.2171A>C p.E724A | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
